Gene-level copy-number profile of tumor specimen HCM-CSHL-0385-C18-01A from HCMI case HCM-CSHL-0385-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 82.2 years (30,009 days).
Specimen HCM-CSHL-0385-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37f3cca8-28dc-4195-9516-0238ac37fd55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0385-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/e08d1150-5009-472b-9304-bea06db32954

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 2: 5,206; copy number 3: 2,669; copy number 4: 36,511; copy number 5: 6,821; copy number 6: 5,753; copy number 7: 3; copy number 8: 791; copy number 9: 38; copy number 10: 569; copy number 72: 9; copy number 80: 21; copy number 105: 6; copy number 117: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 647 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:107,163,510–110,616,353, 40 genes, copy number 72–117 (within-gene range 6–117): FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1.
- chr20:87,250–2,508,907, 73 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:5,113,993–5,929,318, 21 genes, copy number 10: Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1.
- chr20:6,200,989–6,780,246, 7 genes, copy number 10: TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2.
- chr20:25,919,499–32,585,074, 84 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:32,690,180–33,309,871, 21 genes, copy number 10: BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1.
- chr20:34,844,720–36,270,918, 60 genes, copy number 10: GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2.
- chr20:40,004,216–47,188,844, 182 genes, copy number 10 (broad region; genes not listed).
- chr20:52,671,735–57,620,576, 75 genes, copy number 9–10 (broad region; genes not listed).
- chr20:61,252,261–62,762,771, 47 genes, copy number 10: CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2.
- chr20:63,743,668–64,327,972, 37 genes, copy number 9: ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
